CCG case CUPP-B7SY — CCG-CUPP: Center for Cancer Genomics (CCG) Cancers of Unknown Primary Project (CUPP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8bbb15ad-2f9c-4d9b-92cb-b2fa0189bbe9

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age: 90 years or older (exact value withheld by GDC); Vital status: Dead; Days to death: 1,983 days (5.4 years); Year of death: 2009; Cause of death: Cancer Related; Country of birth: United States.

Diagnoses (2; GDC holds 3 diagnosis records for this case, 1 of them empty or duplicates of those shown)
1. Carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8010/3; ICD-10 code: C80.9; Tissue or organ of origin: Unknown primary site; Classification of tumor: primary; Year of diagnosis: 2004; Prior malignancy: yes; Prior treatment: Yes.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: First-Line Therapy.
2. Subsequent primary (histology not recorded by GDC).

Follow-up (1 entry)
- Days to follow up: 1,983 days (5.4 years); Year of follow up: 2009.

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample CUPP-B7SY-TTM1-A: Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide CUPP-B7SY-TTM1-A-1-0-S1: Section location: Top; Percent tumor cells: 32; Percent tumor nuclei: 24; Percent normal cells: 0; Percent necrosis: 4; Percent stromal cells: 64; Percent lymphocyte infiltration: 72; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
